Somatic mutation profile of tumor specimen 0DCXB6 from CCDI case PBBMVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.5 years (2,754 days).
Specimen 0DCXB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52eb0d96-189d-46a9-88ff-afe7e6fddb8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCX8Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68be5c59-6f04-4e66-b717-20cbfb9122a3

The open-access MAF lists 101 somatic variants for this specimen: 75 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 14, Intron 9, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 2, 5'UTR 1, 5'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 304/1031 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571806, COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ABCA5 | c.128del p.L43Yfs*4 | Frame Shift Del (DEL) | VAF 85/277 reads (31%) | catalogued as rs751512043; called by mutect2, varscan2
- AKT1S1 | c.487G>T p.G163C (on ENST00000344175 / NM_001098633.4; = p.G183C on NM_032375.5) | Missense Mutation (SNP) | VAF 217/818 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV100465437; called by muse, mutect2, varscan2
- AMOTL2 | c.2024C>G p.A675G | Missense Mutation (SNP) | VAF 216/597 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.642); catalogued as rs745539705; called by muse, mutect2, varscan2
- ANKRD36C | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 220/721 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1179354220, COSV71727843; called by muse, mutect2, varscan2
- BAZ1B | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 251/1112 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs782307839, COSV59991078, COSV59994858; called by muse, mutect2, varscan2
- CADPS2 | c.3208del p.T1070Qfs*17 | Frame Shift Del (DEL) | VAF 136/893 reads (15%) | catalogued as COSV104395799; called by mutect2, pindel, varscan2
- CDH2 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52298032; called by muse, mutect2, varscan2
- CDH23 | c.8284G>A p.A2762T | Missense Mutation (SNP) | VAF 192/527 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776337745; called by muse, mutect2, varscan2
- CRYBB2 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 281/714 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as rs372174699; called by muse, mutect2, varscan2
- CSMD1 | c.1192G>T p.A398S (on ENST00000520002; = p.A397S on NM_033225.6) | Missense Mutation (SNP) | VAF 257/1206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101227909; called by muse, mutect2, varscan2
- CSNK1E | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 256/723 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1474798176, COSV63291820; called by muse, mutect2, varscan2
- DMD | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 165/205 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as CD103873; called by muse, mutect2, varscan2
- HMCN2 | c.4931C>T p.A1644V | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs773916457; called by muse, mutect2, varscan2
- HS3ST2 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 21/820 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs1438011463, COSV99758554; called by muse, mutect2
- KIF5C | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 211/728 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1158796093, COSV68482492; called by muse, mutect2, varscan2
- KLF12 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 185/533 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1361186909, COSV66582461; called by muse, mutect2, varscan2
- KRT71 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 179/662 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774639201; called by muse, mutect2
- MARK1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 216/538 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767820453, COSV65070769; called by muse, mutect2, varscan2
- MOV10 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 222/603 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs748146686; called by muse, mutect2, varscan2
- NYAP1 | c.1295G>T p.C432F | Missense Mutation (SNP) | VAF 105/515 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as rs757114604; called by muse, mutect2, varscan2
- OR2L5 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 272/676 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62364299; called by muse, mutect2, varscan2
- PCDH15 | c.5074del p.S1692Lfs*152 | Frame Shift Del (DEL) | VAF 200/597 reads (34%) | catalogued as COSV57261962; called by mutect2, pindel, varscan2
- PNKD | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 292/1067 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.294); catalogued as COSV99282248; called by muse, mutect2, varscan2
- RYR2 | c.3507C>G p.N1169K | Missense Mutation (SNP) | VAF 329/768 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.067); catalogued as rs746106606; called by muse, mutect2, varscan2
- SPATA4 | c.230del p.N77Mfs*4 | Frame Shift Del (DEL) | VAF 82/334 reads (25%) | catalogued as rs1162628618; called by pindel, varscan2
- SULF1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 20/721 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52671957; called by muse, mutect2
- TAX1BP1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 153/798 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as rs749998662; called by muse, mutect2, varscan2
- UHRF1 | c.1069G>C p.E357Q (on ENST00000612630 / NM_001290050.1; = p.E370Q on NM_013282.4) | Missense Mutation (SNP) | VAF 237/833 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV99503513; called by muse, mutect2, varscan2
- UTRN | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1562385180; called by muse, mutect2, varscan2
- ZNF44 | c.1855C>T p.R619C (on ENST00000356109 / NM_001164276.2; = p.R571C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 170/567 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs545392196; called by muse, mutect2, varscan2
- ADAMTS5 | c.2350T>C p.Y784H | Missense Mutation (SNP) | VAF 228/565 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK3 | c.1954C>A p.Q652K | Missense Mutation (SNP) | VAF 148/357 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNB1 | c.1575C>A p.D525E | Missense Mutation (SNP) | VAF 197/493 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CDH2 | c.1612T>C p.S538P | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNOT3 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 203/708 reads (29%) | called by muse, mutect2, varscan2
- CNOT6 | c.650G>C p.W217S | Missense Mutation (SNP) | VAF 250/800 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG1 | c.4719-2A>T p.X1573_splice | Splice Site (SNP) | VAF 274/606 reads (45%) | called by muse, mutect2, varscan2
- CSPP1 | c.1561C>G p.R521G (on ENST00000676605; = p.R480G on NM_024790.6) | Missense Mutation (SNP) | VAF 192/1010 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNNA2 | c.1640C>A p.A547E | Missense Mutation (SNP) | VAF 155/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CUBN | c.2213T>C p.M738T | Missense Mutation (SNP) | VAF 226/660 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP7A1 | c.524G>C p.C175S | Missense Mutation (SNP) | VAF 217/1034 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DCTN4 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 186/662 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EN2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 152/732 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ESCO2 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 405/2120 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOXA3 | c.652_654del p.K218del | In Frame Del (DEL) | VAF 127/524 reads (24%) | called by mutect2, pindel, varscan2
- GGH | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 147/695 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GNA11 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 227/858 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HBP1 | c.342G>T p.L114F | Missense Mutation (SNP) | VAF 26/940 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- HEPH | c.556C>A p.H186N (on ENST00000343002; = p.H240N on NM_138737.5) | Missense Mutation (SNP) | VAF 218/273 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IKBKB | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 301/1384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL21 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 139/354 reads (39%) | called by muse, mutect2, varscan2
- IQUB | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 102/502 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- KCND3 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KCNJ5 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 271/1049 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LATS1 | c.2627G>C p.S876T | Missense Mutation (SNP) | VAF 161/375 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- LILRA6 | c.54G>C p.R18S | Missense Mutation (SNP) | VAF 52/593 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- LRFN2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 182/426 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYBL2 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 139/722 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- OXR1 | c.1427A>T p.E476V (on ENST00000442977 / NM_001198532.1; = p.E475V on NM_018002.3) | Missense Mutation (SNP) | VAF 286/1486 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE4DIP | c.3767C>A p.T1256K | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PGS1 | c.334-1G>C p.X112_splice | Splice Site (SNP) | VAF 86/302 reads (28%) | called by muse, mutect2, varscan2
- POLI | c.1926A>C p.Q642H | Missense Mutation (SNP) | VAF 200/683 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRAMEF19 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 209/831 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAPGEF1 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 258/689 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASGRP1 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.10497A>C p.K3499N | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SP110 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 151/641 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TCF24 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 132/603 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TELO2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 136/369 reads (37%) | called by muse, mutect2, varscan2
- TENM2 | c.4231C>G p.Q1411E (on ENST00000518659 / NM_001122679.2; = p.Q1172E on NM_001080428.3) | Missense Mutation (SNP) | VAF 225/749 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TGFBRAP1 | c.2290C>A p.Q764K | Missense Mutation (SNP) | VAF 220/662 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZNF175 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 200/774 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF521 | c.3491_3497del p.L1164Qfs*8 | Frame Shift Del (DEL) | VAF 132/635 reads (21%) | called by mutect2, pindel, varscan2
- ZNF865 | c.3115C>T p.H1039Y | Missense Mutation (SNP) | VAF 174/561 reads (31%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- ACSM1 | c.285C>A p.T95= | Silent (SNP) | VAF 162/420 reads (39%) | called by muse, varscan2
- ALDH16A1 | c.663G>T p.P221= | Silent (SNP) | VAF 258/922 reads (28%) | called by muse, mutect2, varscan2
- CDH9 | c.1848C>T p.L616= | Silent (SNP) | VAF 207/715 reads (29%) | catalogued as rs541154525, COSV99155508; called by muse, mutect2, varscan2
- CELSR1 | c.5811G>T p.G1937= | Silent (SNP) | VAF 43/424 reads (10%) | called by muse, mutect2, varscan2
- DNASE2 | c.456C>A p.T152= | Silent (SNP) | VAF 272/1107 reads (25%) | catalogued as COSV52251240; called by muse, mutect2, varscan2
- DNM2 | c.2355G>A p.R785= (on ENST00000355667 / NM_001005360.3; = p.R781= on NM_004945.3) | Silent (SNP) | VAF 142/396 reads (36%) | called by muse, mutect2, varscan2
- FER | c.198C>T p.N66= | Silent (SNP) | VAF 116/389 reads (30%) | catalogued as rs190188307, COSV55295381; called by muse, mutect2, varscan2
- INPP5B | c.1833G>A p.K611= (on ENST00000373023; = p.K531= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 551/1022 reads (54%) | called by muse, mutect2, varscan2
- LAMA1 | c.5667T>G p.L1889= | Silent (SNP) | VAF 130/540 reads (24%) | called by muse, mutect2, varscan2
- MYLK3 | c.1879C>T p.L627= | Silent (SNP) | VAF 237/624 reads (38%) | catalogued as COSV67364000; called by muse, mutect2, varscan2
- OSBPL1A | c.912T>C p.F304= | Silent (SNP) | VAF 102/468 reads (22%) | catalogued as rs750410099; called by muse, mutect2, varscan2
- RTP1 | c.573C>T p.C191= | Silent (SNP) | VAF 183/521 reads (35%) | catalogued as rs1034641198, COSV56618123; called by muse, mutect2, varscan2
- SEPTIN14 | c.198G>A p.S66= | Silent (SNP) | VAF 168/992 reads (17%) | catalogued as rs758771918, COSV66427353; called by muse, mutect2, varscan2
- TAZ | c.801G>A p.T267= | Silent (SNP) | VAF 172/212 reads (81%) | catalogued as rs781792950, HD080018; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC32 | c.*86_*111del | 3'UTR (DEL) | VAF 95/200 reads (48%) | called by mutect2, pindel, varscan2
- CISD1 | c.-80T>A | 5'UTR (SNP) | VAF 63/126 reads (50%) | called by muse, mutect2, varscan2
- GABBR2 | c.322-28875C>A | Intron (SNP) | VAF 237/606 reads (39%) | called by muse, mutect2
- KIF1B | c.2115+7384C>T | Intron (SNP) | VAF 247/481 reads (51%) | catalogued as rs746409974; called by muse, mutect2, varscan2
- NECTIN2 | c.1043-3807C>T | Intron (SNP) | VAF 135/510 reads (26%) | catalogued as rs748082804, COSV52979284; called by muse, mutect2, varscan2
- PRMT3 | c.772-21G>T | Intron (SNP) | VAF 71/198 reads (36%) | catalogued as rs377173644; called by muse, mutect2, varscan2
- RFTN1 | c.827-65G>A | Intron (SNP) | VAF 50/131 reads (38%) | catalogued as rs950232099, COSV61917123; called by muse, mutect2, varscan2
- SLC12A1 | c.724+488T>G | Intron (SNP) | VAF 80/205 reads (39%) | called by muse, mutect2, varscan2
- SULT1A1 | c.373-189C>T | Intron (SNP) | VAF 54/108 reads (50%) | catalogued as rs1488599754; called by muse, mutect2, varscan2
- TMEM134 | chr11:67469254 C>G | 5'Flank (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- TMEM184A | c.644+64G>A | Intron (SNP) | VAF 100/411 reads (24%) | called by muse, mutect2, varscan2
- ZNF285 | c.15+60C>G | Intron (SNP) | VAF 75/272 reads (28%) | called by muse, mutect2, varscan2
